TCGA case TCGA-BA-A6DA — Head and Neck Squamous Cell Carcinoma (TCGA-HNSC)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026), part of The Cancer Genome Atlas (TCGA). Disease type: Squamous Cell Neoplasms; Primary site: Larynx; Tissue source site: UNC. Index date (day 0 for every day count below): diagnosis.
https://portal.gdc.cancer.gov/cases/17885905-280f-40fa-943e-346ed45403ea

Demographics
Sex at birth: female; Race: white; Ethnicity: not hispanic or latino; Country of residence at enrollment: United States; Age at index: 41 years; Vital status: Alive.

Diagnoses (1)
1. Squamous cell carcinoma, NOS: ICD-O-3 morphology code: 8070/3; ICD-10 code: C32.1; Tissue or organ of origin: Supraglottis; Site of resection or biopsy: Head, face or neck, NOS; Classification of tumor: primary; Age at diagnosis: 41.1 years (15,004 days); Year of diagnosis: 2012; AJCC staging edition: 7th; AJCC clinical T: T4a; AJCC clinical N: N2c; AJCC clinical M: M0; AJCC clinical stage: Stage IVA; AJCC pathologic T: T4a; AJCC pathologic N: N2c; AJCC pathologic M: M0; AJCC pathologic stage: Stage IVA; Tumor grade: G2; Prior malignancy: no; Synchronous malignancy: No; Prior treatment: No; Days to last follow up: 351 days.
   Pathology details: Lymph node dissection method: Modified Radical Neck Dissection; Lymph node dissection site: Neck, Left.
   Pathology details: Lymph node dissection method: Modified Radical Neck Dissection; Lymph node dissection site: Neck, Right.
   Pathology details: Consistent pathology review: Yes; Extranodal extension: Microscopic Extension; Lymph nodes positive: 9; Lymph nodes tested: 87; Lymphatic invasion present: Yes; Margin status: Indeterminate; Perineural invasion present: Yes; Vascular invasion present: Yes.
   Treatment given: Treatment type: Chemotherapy; Therapeutic agents: Cisplatin; Days to treatment start: 68 days; Days to treatment end: 110 days; Treatment outcome: Complete Response.
   Treatment given: Treatment type: Radiation, External Beam; Days to treatment start: 68 days; Days to treatment end: 112 days; Treatment dose: 6,600 cGy; Treatment outcome: Complete Response; Number of fractions: 33; Treatment anatomic sites: Primary Tumor Field.

Follow-up (1 entry)
- Days to follow up: 351 days; Disease response: Tumor Free.

Molecular and laboratory tests
- CDKN2A: Positive.
- Involved Tissue, NOS human papillomavirus (ISH): Negative.

Exposures
- Alcohol history: No; Alcohol drinks per day: 0; Alcohol days per week: 0.
- Exposure type: Tobacco; Tobacco smoking status: Current Smoker; Pack years smoked: 25; Tobacco smoking onset year: 1987.

Biospecimens (3 samples; slide percentages are pathologist estimates recorded by GDC per slide)
- Sample TCGA-BA-A6DA-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Initial weight: 250 mg.
  Slide TCGA-BA-A6DA-01A-02-TS2: Section location: Top; Percent tumor cells: 20; Percent tumor nuclei: 20; Percent normal cells: 20; Percent necrosis: 0; Percent stromal cells: 60; Percent lymphocyte infiltration: 20; Percent monocyte infiltration: 3; Percent neutrophil infiltration: 7.
  Slide TCGA-BA-A6DA-01A-03-TS3: Section location: Top; Percent tumor cells: 100; Percent tumor nuclei: 80; Percent normal cells: 0; Percent necrosis: 0; Percent stromal cells: 0; Percent lymphocyte infiltration: 3; Percent monocyte infiltration: 0; Percent neutrophil infiltration: 1.
- Sample TCGA-BA-A6DA-01Z: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: FFPE; Days to sample procurement: 0 days.
- Sample TCGA-BA-A6DA-10A: Sample type: Blood Derived Normal; Tissue type: Normal; Specimen type: Peripheral Blood NOS.

Additional fields from the legacy TCGA clinical forms (Biospecimen Core Resource XML)
- Enrollment form: Submitted tumor site: Head and Neck; Histologic diagnosis: Head & Neck Squamous Cell Carcinoma; Prospective collection: Yes; Retrospective collection: No; History neoadjuvant treatment: No; Tumor status: Tumor free; Lymph nodes examined: Yes; Lymph node neck dissection indicator: Yes; Margin status: Close; Lymphovascular invasion: Yes; Tobacco smoking history indicator: 2; Alcohol history documented: Yes; Alcohol consumption frequency: 0; Treatment outcome first course: Complete Remission/Response.
- Follow-up form: Lost to follow-up: Yes.

Curated follow-up endpoints (TCGA Pan-Cancer Clinical Data Resource, Liu et al., Cell 2018; times are days from initial pathologic diagnosis to the event or to last contact): overall survival: no event (censored), 351 days; disease-specific survival: no event (censored), 351 days; progression-free interval: no event (censored), 351 days.

Tumor purity and ploidy (ABSOLUTE, TCGA Pan-Cancer Atlas; aliquot TCGA-BA-A6DA-01A-31D-A31K-01): tumor purity 0.48, ploidy 2.14, whole-genome doublings 0.
